Somatic mutation profile of tumor specimen MP2PRT-PARTZA-TMP1-A (aliquot MP2PRT-PARTZA-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PARTZA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,551 days).
Specimen MP2PRT-PARTZA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d15d207-4f1d-44d1-986c-1d8f50c8b1c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARTZA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARTZA-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12bfd4c9-02f7-4824-9212-e442bf1bae90

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Ins 2, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 93/410 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- EPHB2 | c.2305C>T p.R769C (on ENST00000400191 / NM_001309193.2; = p.R770C on NM_004442.7) | Missense Mutation (SNP) | VAF 68/434 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367548936; called by muse, mutect2, varscan2
- GRIP2 | c.1750G>A p.V584M (on ENST00000619221; = p.V487M on NM_001080423.4) | Missense Mutation (SNP) | VAF 105/454 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754111745; called by muse, mutect2, varscan2
- HDAC10 | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 63/403 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755856003; called by muse, mutect2, varscan2
- SBK1 | c.1177G>A p.G393S | Missense Mutation (SNP) | VAF 107/714 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs765029481; called by muse, mutect2, varscan2
- SLC35E4 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 112/704 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778587894; called by muse, mutect2, varscan2
- TTC21A | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs753105759, COSV57186623; called by muse, mutect2, varscan2
- HLX | c.146_147insGGGC p.I49Mfs*132 | Frame Shift Ins (INS) | VAF 91/799 reads (11%) | called by mutect2, pindel, varscan2
- MIPOL1 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 132/339 reads (39%) | called by muse, mutect2, varscan2
- MKS1 | c.1156G>A p.E386K | Missense Mutation (SNP) | VAF 96/390 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- RGS19 | c.173_174dup p.W59Rfs*37 | Frame Shift Ins (INS) | VAF 82/412 reads (20%) | called by mutect2, varscan2
- ZBTB7A | c.1159T>C p.C387R | Missense Mutation (SNP) | VAF 87/532 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C1orf87 | c.1419G>A p.T473= | Silent (SNP) | VAF 107/414 reads (26%) | catalogued as rs149445455; called by muse, mutect2, varscan2
- CRISP3 | c.606T>C p.Y202= (on ENST00000371159 / NM_001368123.1; = p.Y184= on NM_006061.4) | Silent (SNP) | VAF 21/376 reads (6%) | called by muse, mutect2
- LAMA5 | c.5712C>T p.D1904= | Silent (SNP) | VAF 309/720 reads (43%) | catalogued as rs139559822; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3996G>C | Intron (SNP) | VAF 25/361 reads (7%) | called by muse, mutect2
